CCDI case PBBZJH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/781e69e7-5e57-4fd3-bdd8-da201322d18c

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 3.5 years (1,286 days).

Biospecimens (3 samples)
- Sample 0DLJWG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLJWP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLJX8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
